Gene-level copy-number profile of tumor specimen TCGA-X6-A8C2-01A from TCGA case TCGA-X6-A8C2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 56.1 years (20,507 days).
Specimen TCGA-X6-A8C2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.b5be3f1c-5112-4e41-8535-00a200df319f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A8C2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a6e289f2-a8d4-4006-b7b0-52d9d3bc6a04

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 2,452; copy number 2: 22,427; copy number 3: 22,152; copy number 4: 7,084; copy number 5: 4,152; copy number 6: 409; copy number 7: 702; copy number 8: 102; copy number 9: 251.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A8C2-01A-11D-A36I-01): tumor purity 0.79, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:264,140–278,283, 1 gene (within-gene range 0–2): ACP1.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–4): RB1.
- chr13:48,389,567–51,024,120, 57 genes (within-gene range 0–3): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,055 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–27,166,981, 630 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:160,830,160–161,220,699, 29 genes, copy number 7 (within-gene range 2–7): CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G.
- chr1:162,979,551–163,321,894, 7 genes, copy number 7 (within-gene range 2–7): AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1.
- chr1:164,356,767–164,899,296, 6 genes, copy number 7 (within-gene range 5–7): HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1.
- chr1:169,394,870–175,743,616, 132 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:180,509,380–180,566,523, 1 gene, copy number 7 (within-gene range 5–7): OVAAL.
- chr1:180,632,022–180,890,279, 2 genes, copy number 7 (within-gene range 5–7): XPR1, U6.
- chr1:181,236,388–181,238,604, 1 gene, copy number 7: LINC01699.
- chr3:188,941,715–192,917,856, 41 genes, copy number 7–8 (within-gene range 4–8): TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2.
- chr5:58,198–535,882, 23 genes, copy number 8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456.
- chr5:7,707,802–8,457,564, 15 genes, copy number 7: AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4.
- chr5:8,455,946–8,460,999, 3 genes, copy number 7: AC091965.2, AC091965.5, MIR4458.
- chr5:16,373,361–22,853,344, 89 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr5:24,478,516–24,644,978, 4 genes, copy number 8 (within-gene range 6–8): AC010387.2, CDH10, AC091885.2, AC091885.1.
- chr5:33,367,179–36,876,700, 62 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:40,998,017–41,880,210, 7 genes, copy number 7–9: MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1.
- chr17:69,707,193–69,994,845, 3 genes, copy number 8: AC002545.1, LINC01497, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 1,745. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
